CCDI case PBBZUL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ecd55e23-b8b0-4841-ae90-c7cd681d28e2

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 16.4 years (5,978 days).

Biospecimens (3 samples)
- Sample 0DLX4N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLX58: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLX5I: Tissue type: Tumor; Specimen type: Solid Tissue.
